Somatic mutation profile of tumor specimen TCGA-DU-6397-01A (aliquot TCGA-DU-6397-01A-11D-1705-08) from TCGA case TCGA-DU-6397, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 45.7 years (16,695 days).
Specimen TCGA-DU-6397-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76599785-579c-47f4-927a-e83fdc269117.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6397-10A (Blood Derived Normal), aliquot TCGA-DU-6397-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1b266bd-edfa-49a0-998d-ac441b982aba

The open-access MAF lists 27 somatic variants for this specimen: 24 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Frame Shift Del 4, Silent 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 39/100 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRF4 | c.1375A>G p.I459V | Missense Mutation (SNP) | VAF 23/367 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51955338; called by muse, mutect2
- ALPK1 | c.2018C>A p.P673H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV51589062; called by muse, mutect2, varscan2
- ATAD2 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54884477; called by muse, mutect2
- CIC | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50647994, COSV50651212; called by muse, mutect2
- CNTNAP2 | c.3203G>C p.S1068T | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV62225976; called by muse, mutect2
- DDX24 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as rs759757010, COSV58213293; called by muse, mutect2, varscan2
- FLG | c.4390G>C p.G1464R | Missense Mutation (SNP) | VAF 17/239 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.341); catalogued as rs551853917, COSV100911461, COSV64245283, COSV64250597; called by muse, mutect2
- HYDIN | c.2672G>T p.S891I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV58560840; called by mutect2, varscan2
- IQGAP1 | c.4165A>G p.K1389E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200349977; called by muse, mutect2
- KIT | c.1093T>A p.S365T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV55412773; called by muse, mutect2, varscan2
- KRTAP10-7 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV59111769; called by muse, mutect2, varscan2
- OR4M1 | c.76G>T p.V26F | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV60062699; called by muse, mutect2, varscan2
- OR5AC2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as rs755877682, COSV62279133; called by muse, mutect2
- RREB1 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as rs1204423231, COSV58562050; called by muse, mutect2, varscan2
- RUFY2 | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV56260461; called by muse, mutect2, varscan2
- SSTR2 | c.1058C>G p.T353S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV59535761, COSV59536150; called by muse, mutect2, varscan2
- UBLCP1 | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV57144074; called by muse, mutect2, varscan2
- VAV1 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs769393831, COSV58382329; called by muse, mutect2, varscan2
- ERICH5 | c.541dup p.T181Nfs*12 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- FRMD4B | c.2383_2384del p.K795Efs*21 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- FUBP1 | c.11_12del p.Y4Ffs*24 | Frame Shift Del (DEL) | VAF 10/17 reads (59%) | called by mutect2, varscan2
- GXYLT2 | c.1282del p.A428Lfs*26 | Frame Shift Del (DEL) | VAF 8/89 reads (9%) | called by mutect2, pindel
- SS18 | c.569_570del p.Y190Wfs*49 | Frame Shift Del (DEL) | VAF 26/152 reads (17%) | called by mutect2, pindel, varscan2
- CACNA1G | c.6645A>G p.L2215= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV61733226; called by muse, mutect2, varscan2
- RETNLB | c.117C>A p.L39= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV55466036, COSV99848847; called by muse, mutect2
- SNORD116-9 | n.83G>A | RNA (SNP) | VAF 12/190 reads (6%) | catalogued as rs750310563; called by muse, mutect2
